Gene-level copy-number profile of tumor specimen TCGA-56-8201-01A from TCGA case TCGA-56-8201, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.5 years (27,211 days).
Specimen TCGA-56-8201-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.84753097-1797-4136-925e-b786f770fe2a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-8201-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/750a2a0f-a1c6-4f18-b3ef-234913d03a33

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 13,329; copy number 3: 23,767; copy number 4: 19,575; copy number 5: 1,512; copy number 6: 1,500; copy number 8: 35; copy number 9: 23; copy number 36: 3; copy number 44: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-8201-01A-11D-2243-01): tumor purity 0.22, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 130 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:165,747,588–168,247,595, 23 genes, copy number 9 (within-gene range 6–9): GALNT3, AC009495.3, AC009495.1, AC009495.2, TTC21B, TTC21B-AS1, SCN1A-AS1, SCN1A, Y_RNA, RN7SKP152, SCN9A, SCN7A, AC074101.1, XIRP2, AC092601.1, XIRP2-AS1, AC073050.1, RNU7-148P, CTAGE14P, B3GALT1-AS1, B3GALT1, STK39, PHF5GP.
- chr14:56,117,316–58,298,139, 35 genes, copy number 8 (within-gene range 6–8): AL138995.1, PELI2, AL355073.1, AL355073.2, LINC02284, TMEM260, AL355103.1, AL161757.2, AL161757.5, AL161757.1, AL161757.3, OTX2, OTX2-AS1, AL161757.4, RN7SL461P, RNU6-1204P, AL137100.3, RPL3P3, AL137100.1, AL137100.2, AL391152.1, EXOC5, AP5M1, AL355834.2, AL355834.1, NAA30, CCDC198, SLC35F4, AL161804.1, AL136520.1, RN7SKP99, AL049838.1, ARMH4, AL121579.2, UBA52P3.
- chr22:20,889,206–21,885,673, 72 genes, copy number 36–44 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
